MMRF case MMRF_2524 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ed87e0ec-73fa-462e-8be2-dfb9229bbf4d

Demographics
Sex at birth: female; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.2 years (23,821 days); ISS stage: II; Days to last known disease status: 638 days (1.7 years); Days to last follow up: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -26: M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 39.4 mg/dL; Immunoglobulin G 50.9 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 243 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 29 g/L; Total Protein 8.6 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 0.206 mg/dL.
- Day 92: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.25 mg/dL; Immunoglobulin G 17.6 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 10.9 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 6.38 mmol/L.
- Day 182: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 11.3 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.04 mmol/L.
- Day 267 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 7.09 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 9.8 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 5.4 g/dL; Glucose 4.73 mmol/L.
- Day 351 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 5.75 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 5.39 mmol/L.
- Day 463 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.11 mmol/L.
- Day 554 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 8.64 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.46 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 9.59 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day -26: Weight: 105 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2524_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -26 days.
- Sample MMRF_2524_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -26 days.
